FM case AD16950 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/5ee9e757-ff3d-429f-92e4-295f1c66e1c3

Female, 57.6 years: Carcinoma, NOS (ICD-O-3 8010/3) of the breast; primary biopsied or resected from the breast. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
